Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A3PN, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A3PN-01A (Primary Tumor).

PATIENT HISTORY:

No additional history provided.

Not provided.

PRE-OP: Adnexal mass.

POST-OP: Same.

PROCEDURE: Laparoscopy, right salpingo-oophorectomy, lysis of adhesions.

FINAL DIAGNOSIS:PART 1: "ADNEXAL MASS", LEFT, BIOPSY -
LEIOMYOSARCOMA.PART 2: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY -
UNREMARKABLE OVARY AND FALLOPIAN TUBEPART 3: "PELVIC MASS", LEFT, EXCISION -
LEIOMYOSARCOMA, 6.7 CM. (see comment).

Collection Date: 8/2/2006

COMMENT:

Parts 1 and 3: The tumor morphologically demonstrates smooth muscle differentiation. The tumor cells show significant cytologic atypia, which is present diffusely. The mitotic activity in the tumor ranges from 5 mitoses/10 high power fields (hpf) to 13 mitoses/10hpf (slide 3A). There are also patchy areas suggestive of tumor cell necrosis. Given the above morphologic features the tumor is best classified as leiomyosarcoma. No adnexal structures are identified in the specimen. Immunohistochemical stains for estrogen and progesterone receptors are pending and will be reported in an addendum.

Please cross-refer to pelvic wash cytology specimen

Interpreted as negative for malignant cells.

has also reviewed this case and concurs with the diagnosis of leiomyosarcoma.

Addendum

Slides from this case were reviewed at
concurs with our diagnosis of leiomyosarcoma.

The outside pathologist

Addendum

The tumor cells are negative for estrogen and progesterone receptors by immunohistochemistry.

1CD-0-3

leiomyosarcoma, NOS 8890/3

COLF SITE: uterus, NOS C55-9

Path: Uterine adnexa C57.4.

lw

2/15/12

HRPA Discrepancy		X

Source: NCI Genomic Data Commons file 2db6ccc1-6b94-474d-9299-6984fd4663c3 (TCGA-K1-A3PN.F9127ADE-86CA-49AC-B1C9-E851876F8A19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).